FM case AD4672 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/6b7f7638-4a06-4d22-87fa-de1991f80a8c

Male, 51.0 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the prostate gland; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
